Somatic mutation profile of tumor specimen MP2PRT-PATCZK-TMP1-A (aliquot MP2PRT-PATCZK-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PATCZK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,890 days).
Specimen MP2PRT-PATCZK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbb2b860-1259-4e2b-975f-b04126d1783b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCZK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCZK-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a480cc4-9d08-40ef-bc1e-7982cfd09595

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAAP100 | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 175/511 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1051333449, COSV59884484; called by muse, mutect2, varscan2
- KCNU1 | c.995+4_995+7del p.X332_splice | Splice Site (DEL) | VAF 48/186 reads (26%) | catalogued as rs1383152154; called by pindel, varscan2
- MLN | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs776485631, COSV56475577; called by muse, mutect2, varscan2
- MUC16 | c.37595C>T p.S12532F | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV67489576; called by muse, mutect2, varscan2
- TRIM49D1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1438197978; called by muse, mutect2, varscan2
- ZNF462 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 147/454 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs746205272, COSV52937692; called by muse, mutect2, varscan2
- C8orf48 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 160/476 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CDH7 | c.570A>T p.R190S | Missense Mutation (SNP) | VAF 131/375 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- DCHS2 | c.1040G>C p.G347A | Missense Mutation (SNP) | VAF 265/763 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- IGKV1D-37 | c.350_352delinsTCGGG p.P117Lfs*? | Frame Shift Ins (INS) | VAF 51/227 reads (22%) | called by pindel, varscan2*
- NXPE2 | c.1080del p.I361Ffs*20 | Frame Shift Del (DEL) | VAF 58/222 reads (26%) | called by mutect2, pindel*
- DST | c.9579T>G p.T3193= | Silent (SNP) | VAF 97/286 reads (34%) | called by muse, mutect2, varscan2
- KRTCAP3 | c.369C>T p.N123= | Silent (SNP) | VAF 171/491 reads (35%) | catalogued as rs745795576; called by muse, mutect2, varscan2
- PAH | c.12G>A p.A4= | Silent (SNP) | VAF 25/396 reads (6%) | catalogued as rs536605300, COSV100187889; called by muse, mutect2
- RASGRP2 | c.1215G>A p.P405= | Silent (SNP) | VAF 129/408 reads (32%) | catalogued as rs758747785, COSV62449964; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451425 G>A | 5'Flank (SNP) | VAF 232/628 reads (37%) | catalogued as rs1452848842; called by muse, mutect2, varscan2
